TCGA case TCGA-FA-A4BB — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1843c82e-7a35-474f-9f79-c0a9af9aa09c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of axilla or arm; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 67.3 years (24,590 days); Year of diagnosis: 2012; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 132 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Lymph Node, Axillary / Lymph Node, Inguinal / Spleen / Liver / Other.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Bone marrow malignant cells: No; Consistent pathology review: Yes; Greatest tumor dimension: 3.5 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CAV + Bleomycin + Etoposide; Days to treatment start: 13 days; Days to treatment end: 132 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CAV + Bleomycin + Etoposide; Days to treatment start: 56 days; Days to treatment end: 62 days; Number of cycles: 1.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CAV + Bleomycin + Etoposide; Days to treatment start: 101 days; Days to treatment end: 108 days; Number of cycles: 1.
   Recorded as not given: Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Days to follow up: -10 days; Disease response: With Tumor.
- Days to follow up: 132 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: within 2 months after completion of first-course treatment.

Molecular and laboratory tests
- CD20 (IHC): Positive.
- CD30 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; Height: 178 cm; BMI: 26.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FA-A4BB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,430 mg.
  Slide TCGA-FA-A4BB-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 2; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-FA-A4BB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FA-A4BB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: HIV status: Negative.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal involvment other: Spleen; Extranodal site involvement: 2.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary; Lymph node involvement site: Inguinal.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Liver; Submitted tumor site: Other Extranodal Site.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: CD30; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: Pet scan after treatment results: Not Done; Treatment outcome at TCGA followup: Complete Remission/Response.
- Drug treatment 1: Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CAV+Bleomycin+Etoposide.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 132 days; disease-specific survival: no event (censored), 132 days; progression-free interval: no event (censored), 132 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FA-A4BB-01A-11D-A31W-01): tumor purity 0.23, ploidy 2.03, whole-genome doublings 0.
